Gene-level copy-number profile of tumor specimen TCGA-61-1916-02A from TCGA case TCGA-61-1916, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 53.3 years (19,463 days).
Specimen TCGA-61-1916-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.355408fe-aef5-4207-964d-34ec652840f5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1916-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/7e7621c3-5eb3-4606-bd1c-2479d9c52471

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,066; copy number 2: 18,990; copy number 3: 13,184; copy number 4: 21,275; copy number 5: 3,526; copy number 6: 1,110; copy number 7: 81; copy number 8: 415; copy number 9: 7; copy number 10: 9; copy number 12: 43; copy number 13: 21; copy number 16: 6; copy number 18: 72; copy number 20: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 164 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:73,168,119–73,520,070, 17 genes, copy number 12 (within-gene range 5–12): FAM149B1, DNAJC9, Y_RNA, EIF4A2P2, AC016394.2, DNAJC9-AS1, MRPS16, DNAJC9-AS1, CFAP70, RNU6-833P, Y_RNA, ANXA7, AL512656.1, RPL26P6, MSS51, PPP3CB, PPP3CB-AS1.
- chr10:73,529,051–73,538,391, 2 genes, copy number 12: RNU6-883P, RPS26P41.
- chr10:74,821,610–75,089,725, 7 genes, copy number 9: AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13.
- chr10:76,835,377–79,516,440, 42 genes, copy number 10–16: AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1, KCNMA1-AS3, COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1.
- chr11:75,815,210–76,144,232, 1 gene, copy number 18 (within-gene range 4–18): UVRAG.
- chr11:75,914,201–81,431,520, 87 genes, copy number 10–20 (within-gene range 6–20) (broad region; genes not listed).
- chr12:17,083,531–17,711,046, 8 genes, copy number 13: AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 1,066. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
